Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A91N, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A91N-01A (Primary Tumor).

[page 1 of 2]
Collect date:

ICD O-3
Adenocarcinoma, tubular
8211/3
Site: Gastric antrum
C16.3
9603/18/14

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Antrum)

I-) Hepatogastric ligament:

-Fibrous and fat tissue uninvolved by neoplasia.

II-) Peripancreatic peritoneum:

-Uninvolved by neoplasia.

III-) Stomach:

-Moderately differentiated tubular adenocarcinoma, vegetating and invasive, located in pyloric antrum and extensive to duodenum, and with largest size: 4.5 cm.

-Tumor infiltrates perigastric fat tissue and peritoneum.

-Presence of lymphatic invasion.

-Venous invasion and perineural invasion not observed.

-Moderate stromal desmoplasia.

-Absence of intratumoral lymphocytic infiltrate.

-Surgical margins uninvolved by neoplasia.

-Non neoplastic mucosa with atrophic gastritis and with extensive intestinal metaplasia.

IV-) Omentum:

-Uninvolved by neoplasia.

V-) Lymphadenectomy following standardization:

*Right paracardic lymph nodes:

-Uninvolved by neoplasia (0/3).

*Lesser curvature lymph nodes:

-Metastatic adenocarcinoma (2/3), with extracapsular extension.

*Left gastroepiploic region:

-Fat tissue without particularities.

-Sample without lymph nodes.

*Right gastroepiploic region:

-Metastatic adenocarcinoma (5/8), with extracapsular extension.

*Infrapyloric lymph nodes:

-Metastatic adenocarcinoma (3/4), with extracapsular extension.

[page 2 of 2]
*Left gastric artery:

-Metastatic adenocarcinoma (5/8), with extracapsular extension.

*Celiac trunk lymph nodes:

-Metastatic adenocarcinoma (3/6), with extracapsular extension.

Dual/Synchronous Pathology Noted		✓
Case is (rele):	QUALIFIED	UNQUALIFIED

Source: NCI Genomic Data Commons file 50548f27-5d92-4116-8fa8-df638847b944 (TCGA-VQ-A91N.EC5FFDFF-128F-43B7-91E0-1EF5185C202D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).